Gene-level copy-number profile of tumor specimen TCGA-50-6592-01A from TCGA case TCGA-50-6592, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 71.7 years (26,191 days).
Specimen TCGA-50-6592-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.321e0572-cc49-461a-acf2-17e603bb29af.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-50-6592-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0d309838-6df9-4ca8-b9e3-c8065983055c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,841; copy number 2: 14,078; copy number 3: 22,143; copy number 4: 16,065; copy number 5: 2,495; copy number 6: 1,193; copy number 7: 360; copy number 8: 234; copy number 9: 175; copy number 10: 115; copy number 11: 71; copy number 13: 9; copy number 18: 26; copy number 24: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-50-6592-01A-11D-1752-01): tumor purity 0.28, ploidy 2.38, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 996 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:899,462–1,744,852, 13 genes, copy number 7: LINC01939, AC113607.1, SNTG2-AS1, SNTG2, AC114808.1, AC114808.2, AC108462.1, AC105450.1, TPO, AC141930.1, AC141930.2, AC144450.1, PXDN.
- chr3:184,186,023–198,222,513, 327 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr4:153,948,718–154,491,799, 4 genes, copy number 8 (within-gene range 5–8): AC079298.3, DCHS2, AC079298.1, AC079298.2.
- chr5:9,035,033–9,546,075, 1 gene, copy number 11 (within-gene range 6–11): SEMA5A.
- chr5:9,363,275–15,384,853, 86 genes, copy number 11–24 (broad region; genes not listed).
- chr6:28,994,785–29,313,017, 20 genes, copy number 7: ZNF311, OR2AD1P, AL662791.2, OR2W1, OR2P1P, SAR1AP1, OR2B3, OR2J1, OR2J3, AL645937.2, AL645937.1, AL645937.4, OR2J2, OR2J4P, AL645937.3, AL672167.1, OR2G1P, OR2U1P, OR2U2P, OR14J1.
- chr6:31,367,057–32,224,067, 116 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr6:44,209,766–44,553,281, 16 genes, copy number 11: RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B, AL353588.1, TCTE1, AARS2, SPATS1, CDC5L, MIR4642, AL136140.1, AL136140.2.
- chr8:95,947,781–103,230,305, 164 genes, copy number 9–13 (within-gene range 4–13) (broad region; genes not listed).
- chr8:103,154,614–103,154,689, 1 gene, copy number 10: MIR3151.
- chr8:104,330,324–114,791,929, 92 genes, copy number 9–13 (broad region; genes not listed).
- chr8:129,415,949–134,723,949, 73 genes, copy number 7 (broad region; genes not listed).
- chr10:44,712–1,737,525, 28 genes, copy number 7 (within-gene range 6–7): AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1, LARP4B, AL359878.2, AL359878.1, GTPBP4, IDI2, IDI2-AS1, IDI1, WDR37, LINC00200, ADARB2, AL392083.2, AL392083.1, AL513304.1, ADARB2-AS1.
- chr16:78,981,722–80,167,577, 21 genes, copy number 7: AC027279.3, AC027279.2, AC009145.4, AC009145.3, AC009145.1, AC009145.2, AC092376.2, AC092376.3, AC092376.1, RNA5SP431, AC084064.1, MAF, AC009159.2, AC009159.3, AC009159.1, AC009159.4, LINC01229, MAFTRR, LINC01228, AC092130.1, AC022166.1.
- chr16:80,179,129–80,180,682, 1 gene, copy number 7: AC022166.2.
- chr20:49,794,811–50,691,542, 33 genes, copy number 7: RNU6-919P, SLC9A8, AL162615.1, SPATA2, Y_RNA, Metazoa_SRP, RNF114, KRT18P4, RNU6-147P, SNAI1, TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271, RN7SL636P, COX6CP2, PTPN1, RN7SL672P, Y_RNA, AL133230.1, MIR645, RIPOR3, MIR1302-5, RPL36P2, RIPOR3-AS1.

Autosomal genes at a single copy (total copy number 1): 1,049. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
